Gene-level copy-number profile of tumor specimen TCGA-25-1329-01A from TCGA case TCGA-25-1329, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.9 years (28,093 days).
Specimen TCGA-25-1329-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5b2ef5e1-b131-4220-9a34-6650e8656e76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1329-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9d1b3e7-20c0-4fee-8aeb-e08baa96984b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 777; copy number 2: 14,787; copy number 3: 19,706; copy number 4: 16,445; copy number 5: 3,692; copy number 6: 225; copy number 7: 1,280; copy number 8: 1,933; copy number 9: 629; copy number 10: 220; copy number 11: 14; copy number 47: 85; copy number 49: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-1329-01A-01D-0452-01): tumor purity 0.81, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,185 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:55,879,835–145,066,685, 1,391 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr12:21,797,401–23,251,499, 23 genes, copy number 49 (within-gene range 3–49): ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:23,637,973–23,638,487, 1 gene, copy number 49: AC087260.1.
- chr12:24,583,561–27,972,733, 85 genes, copy number 47 (broad region; genes not listed).
- chr19:17,452,211–18,671,721, 70 genes, copy number 8 (broad region; genes not listed).
- chr19:23,739,195–58,605,223, 1,703 genes, copy number 7–8 (broad region; genes not listed).
- chr20:11,345,383–12,381,255, 14 genes, copy number 11: RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.
- chr20:30,278,906–64,313,132, 898 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
